CCDI case PBCGHR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/04e6cdc0-92bc-48ee-9c4d-e71272a8dbf5

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 6.1 years (2,234 days).

Biospecimens (3 samples)
- Sample 0DRY7P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRY7V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRY85: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
